CCDI case PBBKPM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/55a79e4e-ef8f-4579-9fec-b179077edc92

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.6 years (3,873 days).

Biospecimens (3 samples)
- Sample 0DECX2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DECXA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DECXF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
